Somatic mutation profile of tumor specimen HCM-CSHL-0085-C24-01A (aliquot HCM-CSHL-0085-C24-01A-01D-A78L-36) from HCMI case HCM-CSHL-0085-C24, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Ampulla of Vater; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,466 days).
Specimen HCM-CSHL-0085-C24-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1dd9c688-c507-4c2c-a1ae-5592ec79eaf8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0085-C24-10A (Blood Derived Normal), aliquot HCM-CSHL-0085-C24-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07ceb3d7-8071-4b99-b13a-bf3e84f21f43

The open-access MAF lists 115 somatic variants for this specimen: 72 protein-altering or splice-affecting, 33 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 33, Intron 5, Nonsense Mutation 3, Splice Region 2, RNA 2, 5'UTR 1, Frame Shift Ins 1, 5'Flank 1, In Frame Del 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.121A>G p.T41A | Missense Mutation (SNP) | VAF 134/505 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs121913412, COSV62687862, COSV62689580, COSV62714770; ClinVar: conflicting interpretations of pathogenicity / pathogenic /  other / likely pathogenic; called by muse, mutect2, varscan2
- AC013489.1 | c.568G>A p.D190N | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.259); catalogued as COSV51552966; called by muse, mutect2, varscan2
- ADGRB1 | c.2202G>A p.A734= | Splice Region (SNP) | VAF 23/140 reads (16%) | catalogued as rs753558928; called by muse, mutect2, varscan2
- ADGRB1 | c.4604G>A p.R1535Q | Missense Mutation (SNP) | VAF 130/400 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.988); catalogued as COSV60097426; called by muse, mutect2, varscan2
- ANK2 | c.2365G>A p.A789T | Missense Mutation (SNP) | VAF 83/723 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.596); catalogued as rs1238418730; called by muse, mutect2, varscan2
- ARID2 | c.1352del p.S451Lfs*12 | Frame Shift Del (DEL) | VAF 37/136 reads (27%) | catalogued as COSV57600163; called by mutect2, pindel, varscan2
- CALHM2 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 41/279 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.322); catalogued as rs377104588; called by muse, mutect2, varscan2
- CSN1S1 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.311); catalogued as rs372612450, COSV55891851; called by muse, mutect2, varscan2
- DACT3 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 29/139 reads (21%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.564); catalogued as rs1267678211; called by muse, mutect2, varscan2
- EPHA1 | c.2671C>T p.R891W | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs767930814; called by muse, mutect2, varscan2
- ESPNL | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs927691376; called by muse, mutect2
- FCGRT | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV54543655; called by muse, mutect2, varscan2
- FERD3L | c.97T>G p.F33V | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV51761712; called by muse, mutect2, varscan2
- FNIP1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 24/396 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs192426636; called by muse, mutect2
- FSTL5 | c.1507_1508dup p.W503Cfs*37 | Frame Shift Ins (INS) | VAF 25/192 reads (13%) | catalogued as COSV60196626; called by mutect2, varscan2
- HCAR3 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 40/318 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs368546949; called by muse, mutect2, varscan2
- HOGA1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 66/465 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs754634699, COSV65706481; called by muse, mutect2, varscan2
- ICAM5 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 79/506 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV55748939; called by muse, mutect2, varscan2
- LRRTM4 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.259); catalogued as COSV69142997; called by muse, mutect2, varscan2
- MCRIP1 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs754717613; called by muse, mutect2, varscan2
- NUGGC | c.748C>T p.R250C | Missense Mutation (SNP) | VAF 36/464 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.966); catalogued as rs774319196, COSV58438380, COSV58439107; called by muse, mutect2
- OR2J2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 32/231 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs755187820; called by muse, mutect2, varscan2
- OR4A16 | c.260A>C p.K87T | Missense Mutation (SNP) | VAF 105/314 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV59042819; called by muse, mutect2, varscan2
- P2RY14 | c.937C>A p.P313T | Missense Mutation (SNP) | VAF 17/192 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV56391075; called by muse, mutect2
- PARP10 | c.2545C>T p.R849C | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs782649313, COSV57299228; called by muse, mutect2, varscan2
- PCDHB15 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.612); catalogued as rs1554292027; called by muse, mutect2, varscan2
- PLEKHM3 | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 56/186 reads (30%) | catalogued as rs1447181721; called by muse, mutect2, varscan2
- PLXND1 | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 45/371 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs554042254; called by muse, mutect2, varscan2
- PRR23A | c.779G>A p.R260H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV67214028; called by muse, mutect2, varscan2
- RAD50 | c.1892A>C p.D631A | Missense Mutation (SNP) | VAF 56/425 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1372866109; called by muse, mutect2, varscan2
- RYR3 | c.13120C>T p.R4374W (on ENST00000389232; = p.R4375W on NM_001036.6) | Missense Mutation (SNP) | VAF 32/420 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs759909362, COSV66778249; called by muse, mutect2
- SRD5A1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 61/234 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57014835; called by muse, mutect2, varscan2
- SYNE2 | c.8033G>A p.G2678E | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.001); catalogued as COSV59955623; called by muse, mutect2
- TDRD9 | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.132); catalogued as rs142470189; called by muse, mutect2, varscan2
- TPTE2 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV55023847; called by muse, mutect2, varscan2
- TRDN | c.278G>A p.R93H | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1371219098, COSV100522147; called by muse, mutect2, varscan2
- TTN | c.31129G>A p.A10377T (on ENST00000591111; = p.A9450T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/144 reads (19%) | PolyPhen benign (0.025); catalogued as rs756672871; called by muse, mutect2, varscan2
- UNC5C | c.2225G>A p.R742H | Missense Mutation (SNP) | VAF 35/305 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs142722408; called by muse, mutect2, varscan2
- ZBTB20 | c.1690G>A p.A564T (on ENST00000474710 / NM_001164342.2; = p.A491T on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs768674584; called by muse, mutect2
- ZNF675 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs568517189, COSV63095135; called by muse, mutect2, varscan2
- ZSCAN9 | c.987G>C p.Q329H | Missense Mutation (SNP) | VAF 37/267 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.378); catalogued as COSV99356463; called by muse, mutect2, varscan2
- ANK2 | c.2694-4C>T | Splice Region (SNP) | VAF 60/498 reads (12%) | called by muse, mutect2, varscan2
- AP5M1 | c.593G>A p.W198* | Nonsense Mutation (SNP) | VAF 94/347 reads (27%) | called by muse, mutect2, varscan2
- ARID1A | c.4984A>T p.K1662* | Nonsense Mutation (SNP) | VAF 16/41 reads (39%) | called by mutect2, varscan2
- ASCL3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, varscan2
- CCDC141 | c.1684C>A p.Q562K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by mutect2, varscan2
- CDH12 | c.1967A>C p.N656T | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPHA5 | c.520A>T p.I174F | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ESF1 | c.1712G>C p.S571T | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GPR75 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 81/284 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- HMCN2 | c.12859G>C p.E4287Q | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- IPO7 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- KIAA1109 | c.12448T>C p.F4150L | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); called by muse, mutect2
- LRRC66 | c.624C>G p.F208L | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- MAL2 | c.416C>G p.P139R | Missense Mutation (SNP) | VAF 49/382 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- NRDC | c.2434G>C p.D812H | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- PHKG1 | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 22/125 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PIP5K1C | c.1819G>A p.A607T | Missense Mutation (SNP) | VAF 95/792 reads (12%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLK2 | c.1051G>C p.V351L | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PPP1R3A | c.2363G>T p.C788F | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRKDC | c.1068_1070del p.N356del | In Frame Del (DEL) | VAF 36/214 reads (17%) | called by pindel, varscan2
- PTGER3 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RGS20 | c.559G>A p.A187T (on ENST00000297313 / NM_170587.4; = p.A40T on NM_003702.4) | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.041); called by muse, varscan2
- RNF6 | c.349T>C p.F117L | Missense Mutation (SNP) | VAF 93/340 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- RYR3 | c.6783A>C p.Q2261H | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SEMA3A | c.1003T>G p.F335V | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SF3A3 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 57/244 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SLC6A4 | c.1387G>C p.E463Q | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.56612A>C p.K18871T (on ENST00000591111; = p.K11447T on NM_003319.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- XYLT2 | c.456G>C p.Q152H | Missense Mutation (SNP) | VAF 113/423 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZDHHC6 | c.404G>A p.C135Y | Missense Mutation (SNP) | VAF 52/259 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZSCAN29 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- ADAMTS16 | c.1287C>T p.F429= | Silent (SNP) | VAF 30/191 reads (16%) | called by muse, mutect2, varscan2
- AKIRIN1 | c.393A>G p.T131= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs1298893257; called by muse, varscan2
- ALPK2 | c.3045C>T p.T1015= | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as rs541753586; called by muse, mutect2, varscan2
- ANKRD1 | c.657C>A p.L219= | Silent (SNP) | VAF 88/715 reads (12%) | catalogued as COSV100865362; called by muse, mutect2, varscan2
- ARPP21 | c.1317A>G p.A439= | Silent (SNP) | VAF 15/434 reads (3%) | catalogued as COSV51806064; called by muse, mutect2
- ASCL3 | c.18C>T p.G6= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as COSV100366920; called by muse, varscan2
- C3AR1 | c.183C>T p.F61= | Silent (SNP) | VAF 47/296 reads (16%) | called by muse, mutect2, varscan2
- CCDC160 | c.582G>A p.T194= | Silent (SNP) | VAF 68/134 reads (51%) | catalogued as rs751796060, COSV66251327; called by muse, mutect2, varscan2
- CLCA1 | c.1791G>A p.T597= | Silent (SNP) | VAF 78/602 reads (13%) | catalogued as rs899149911, COSV52327435; called by muse, mutect2, varscan2
- DDX3X | c.228T>C p.D76= (on ENST00000399959; = p.D77= on NM_001356.5) | Silent (SNP) | VAF 50/162 reads (31%) | called by muse, mutect2, varscan2
- DEPDC5 | c.2256G>T p.L752= (on ENST00000400246; = p.L821= on NM_014662.5) | Silent (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2, varscan2
- ENAM | c.3264G>A p.T1088= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as rs751620386; called by muse, mutect2
- FAT4 | c.10095A>C p.R3365= | Silent (SNP) | VAF 42/321 reads (13%) | called by muse, mutect2, varscan2
- GRIN1 | c.114C>T p.H38= | Silent (SNP) | VAF 74/460 reads (16%) | catalogued as rs1241572680, COSV59300354; called by muse, mutect2, varscan2
- HDAC7 | c.1980T>C p.G660= (on ENST00000427332; = p.G699= on NM_015401.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/194 reads (20%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.228C>T p.I76= | Silent (SNP) | VAF 62/786 reads (8%) | catalogued as rs368264920; called by muse, mutect2
- IL4 | c.147C>T p.T49= | Silent (SNP) | VAF 18/156 reads (12%) | catalogued as rs759103191; called by muse, mutect2, varscan2
- KRT5 | c.75G>A p.P25= | Silent (SNP) | VAF 27/212 reads (13%) | catalogued as rs572849401; called by muse, mutect2, varscan2
- LRRC71 | c.18C>T p.S6= | Silent (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- MDGA2 | c.372A>T p.G124= | Silent (SNP) | VAF 80/330 reads (24%) | called by muse, mutect2, varscan2
- NPRL2 | c.354C>T p.F118= | Silent (SNP) | VAF 52/350 reads (15%) | catalogued as rs928016141, COSV51600078; called by muse, mutect2, varscan2
- OLIG2 | c.168C>T p.R56= | Silent (SNP) | VAF 46/357 reads (13%) | called by muse, mutect2, varscan2
- OR56B4 | c.810G>A p.E270= | Silent (SNP) | VAF 127/482 reads (26%) | called by muse, mutect2, varscan2
- PAXIP1 | c.2868C>T p.F956= | Silent (SNP) | VAF 43/314 reads (14%) | called by muse, mutect2, varscan2
- PGBD5 | c.894C>T p.R298= (on ENST00000525115; = p.R367= on NM_001258311.2) | Silent (SNP) | VAF 21/228 reads (9%) | catalogued as rs1435951071; called by muse, mutect2
- PROM1 | c.2094C>T p.S698= | Silent (SNP) | VAF 39/223 reads (17%) | catalogued as rs199727800, CM1312881; called by muse, mutect2, varscan2
- SOX21 | c.57G>A p.S19= | Silent (SNP) | VAF 117/988 reads (12%) | catalogued as COSV65375414; called by muse, mutect2, varscan2
- SYDE1 | c.819C>T p.Y273= | Silent (SNP) | VAF 19/124 reads (15%) | catalogued as rs1413962871; called by muse, mutect2, varscan2
- TFEB | c.37C>A p.R13= | Silent (SNP) | VAF 27/187 reads (14%) | catalogued as COSV57824244; called by muse, mutect2, varscan2
- TRPM8 | c.2286G>A p.S762= | Silent (SNP) | VAF 199/686 reads (29%) | catalogued as rs199933698, COSV61222637; called by muse, mutect2, varscan2
- UBE3A | c.1372C>T p.L458= | Silent (SNP) | VAF 30/244 reads (12%) | called by muse, mutect2, varscan2
- UMODL1 | c.2307C>T p.I769= (on ENST00000408910 / NM_001004416.2; = p.I897= on NM_173568.3) | Silent (SNP) | VAF 31/264 reads (12%) | called by muse, mutect2, varscan2
- ZWILCH | c.1020C>T p.F340= | Silent (SNP) | VAF 25/328 reads (8%) | catalogued as rs769354705; called by muse, mutect2
- ARMCX4 | c.1038+221C>T | Intron (SNP) | VAF 18/135 reads (13%) | catalogued as rs1395663795, COSV61449959; called by muse, mutect2, varscan2
- CREB5 | chr7:28409791 G>A | 5'Flank (SNP) | VAF 11/83 reads (13%) | catalogued as rs1461952039; called by muse, mutect2, varscan2
- EP300 | c.*2G>C | 3'UTR (SNP) | VAF 21/169 reads (12%) | catalogued as COSV54326918; called by muse, mutect2, varscan2
- FAT3 | c.13052-613G>A | Intron (SNP) | VAF 32/343 reads (9%) | called by muse, mutect2
- FOXP2 | c.168+36459C>T | Intron (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- GALNT13 | c.1531-3742T>C | Intron (SNP) | VAF 30/248 reads (12%) | called by muse, mutect2, varscan2
- LEPR | c.-120C>G | 5'UTR (SNP) | VAF 118/436 reads (27%) | called by muse, mutect2
- PARGP1 | n.1966C>T | RNA (SNP) | VAF 32/353 reads (9%) | catalogued as rs1374034744; called by muse, mutect2, varscan2
- UBTFL2 | n.483A>G | RNA (SNP) | VAF 181/677 reads (27%) | catalogued as rs1433232626; called by muse, mutect2, varscan2
- ZNF589 | c.97-3971G>A | Intron (SNP) | VAF 47/293 reads (16%) | called by muse, mutect2, varscan2
